Surgical pathology report (de-identified scan), TCGA case TCGA-94-8490, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - Emory, specimen TCGA-94-8490-01A (Primary Tumor).

[page 1 of 5]
Anat Path Reports

* Final Report *

Document Type:
Document Date:
Document Status:
Document Title:
Performed By:
Verified By:
Encounter info:

* Final Report *

APRPT (Verified)

Final Surgical Pathology Report

Final Pathologic Diagnosis

- A. LYMPH NODE, #7, EXCISION, A1FS:
- ONE LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA (0/1).
- B. LYMPH NODE, #4R, EXCISION, B1FS:
- ONE LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA (0/1).
- C. LYMPH NODE, 11R, EXCISION:
- ONE LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA (0/1).
- D. LYMPH NODE, LEVEL 7# , EXCISION:
- ONE LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA (0/1).
- E. RIGHT LUNG, PNEUMONECTOMY, E1FS:
- MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA, MULTIPLE NODULES.

Printed by:
Printed on:

Page 1 of 5
(Continued)

[page 2 of 5]
Anat Path Reports

* Final Report *

- BRONCHIAL AND VASCULAR MARGINS OF RESECTION ARE NEGATIVE FOR CARCINOMA.
- NO PLEURAL OR LYMPHOVASCULAR INVASION IS IDENTIFIED.
- RIGHT UPPER LOBE WITH POST OBSTRUCTIVE PNEUMONIA.
- ONE HILAR LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA (0/1).
- SEE SYNOPSIS REPORT AND COMMENT.

F. LYMPH NODE, #10R, EXCISION:

- ONE LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA (0/1).

G. LYMPH NODE, 4R, EXCISION:

- ONE LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA (0/1).

H. LYMPH NODE, LEVEL 7, EXCISION:

- ONE LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA (0/1).

Comment

The tumor is staged as pT3 due to the separate tumor nodule present in the same lobe, away from the main central tumor.

Synoptic Worksheet

E. Right lung; please look at bronchial margin.:

Specimen:	Lung
Procedure:	Pneumonectomy
Specimen Integrity:	Intact
Specimen Laterality:	Right
Tumor Site:	Upper lobe
Tumor Focality:	Separate tumor nodules in same lobe
Histologic Type:	Squamous cell carcinoma
Histologic Grade:	G2: Moderately differentiated
Tumor Size:	Greatest dimension: 5.5 cm
	Additional dimension: 4.0 cm
	Additional dimension: 3.5 cm
Visceral Pleura Invasion:	Not identified
Tumor Extension:	Not applicable
Bronchial Margin:	Uninvolved by invasive carcinoma
	Involvement by squamous cell carcinoma in situ (CIS) not applicable
Vascular Margin:	Uninvolved by invasive carcinoma
Parenchymal Margin:	Not applicable

[page 3 of 5]
Parietal Pleural Margin: Not applicable
Chest Wall Margin: Not applicable
Other Attached Tissue Margin: Not applicable
All Margins Uninvolved By Invasive Carcinoma:
Distance of invasive carcinoma from closest margin: 18 mm
Margin closest to invasive carcinoma: bronchial margin
Treatment Effect: Not applicable
Lymph-Vascular Invasion: Not identified
Extranodal Extension: Not identified
TNM Descriptors: Not applicable
Primary Tumor (pT): pT3: Tumor greater than 7 cm in greatest dimension; or Tumor of any size that directly invades any of the following: chest wall (including superior sulcus tumors), diaphragm, phrenic nerve, mediastinal pleura, parietal pericardium; or Tumor of any size in the main bronchus less than 2 cm distal to the carina but without involvement of the carina; or Tumor of any size associated with atelectasis or obstructive pneumonitis of the entire lung; or Tumors of any size with separate tumor nodule(s) in same lobe
Regional Lymph Nodes (pN): pN0: No regional lymph node metastasis
Nodes examined: 8
Nodes involved: 0
Distant Metastasis (pM): Not applicable
Tumor Associated Atelectasis or Obstructive Pneumonitis:
Extends to the hilar region but does not involve entire lung
Additional Pathologic Findings: Squamous dysplasia
Metaplasia, type: squamous metaplasia
Inflammation, type: post obstructive pneumonia
Emphysema

Clinical History

Mediastinoscopy. Mediastinal lymphadenopathy. Right thoracotomy with bilobectomy, pneumonectomy.

Specimen(s) Received

A: #7 Lymph node
B: #4R Lymph node
C: 11R lymph node
D: LVL 7# lymph node
E: Right lung; please look at bronchial margin.
F: LVL 10R lymph node
G: LVL 4R lymph node
H: Level 7 lymph node

Gross Description

Printed by:
Printed on:

[page 4 of 5]
Eight specimens are received.

Specimen A is received fresh for intraoperative consultation, labeled with the patient's name, medical record number and is designated as "#7 lymph node" and contains multiple black soft tissue fragments measuring in aggregate 0.9 x 0.6 x 0.2 cm. The entire specimen is submitted for intraoperative frozen section consultation and is resubmitted in cassette "A1FS." (Dictated by [REDACTED])

Specimen B is received fresh for intraoperative consultation, labeled with the patient's name, medical record number and is designated as "4R lymph node" and contains multiple fragments of black soft tissue measuring in aggregate 1.0 x 0.7 x 0.2 cm. The entire specimen is submitted for intraoperative frozen section consultation and is resubmitted in cassette "B1FS." (Dictated by [REDACTED])

Specimen C is received in formalin and is labeled with the patient's name, medical record number and "11R lymph node." It consists of multiple irregular fragments of tan to black firm tissue measuring in aggregate 2.5 x 1.8 x 0.4 cm. The specimen is filtered through a biopsy bag and submitted entirely in cassettes "C1" and "C2." (Dictated by [REDACTED])

Specimen D is received in formalin and is labeled with the patient's name, medical record number and "LVL #7 lymph node." It consists of a fragment of tan to black firm tissue measuring 0.8 x 0.8 x 0.2 cm. The specimen is submitted entirely in a biopsy bag in cassette "D1." (Dictated by [REDACTED])

Part E is received fresh, labeled with the patient's name and medical record number. The specimen consists of a right lung measuring 25.0 x 17.0 x 7.0 cm and weighing 1077.5 grams. A centrally located mass that appears to be confined to the upper lobe is identified measuring 5.5 x 4.0 x 3.5 cm and appears to arise from the bronchus just distal to the right upper lobe bronchus. The mass arises from the epithelium 1.8 cm from the bronchial margin. No areas of pleural puckering are identified and the mass comes within 0.8 cm of the pleura. Copious purulent fluid is identified within bronchioles and the parenchyma of the upper lobe demonstrates patchy consolidations. There are several white irregular nodules that range in size from 0.8 to 2.5 cm. These nodules are 5 to 6 cm away from the main tumor, they abut the pleura, and they are discontinuous from the main mass. On the posterior aspect of the lung, tumor appears to come within 0.3 cm of the pleura, however, it appears that this tumor mass is located within large bronchi. The lung parenchyma of the middle and lower lobes appear unremarkable. Dictated by Dr. [REDACTED]

Specimen F is received in formalin and is labeled with the patient's name, medical record number and "LVL R#10 lymph node." It consists of three nodular fragments of brown to black tissue ranging in size from 0.7 to 1.0 cm in greatest dimension. The specimen is filtered through a biopsy bag and submitted entirely in cassette "F1." (Dictated by [REDACTED])

Specimen G is received in formalin and is labeled with the patient's name, medical record number and "LVL 4R lymph node." It consists of a nodular fragment of fibrofatty tissue measuring 1.8 x 1.5 x 0.6 cm. A lymph node is identified measuring 1.0 x 0.8 x 0.3 cm. The lymph node is bisected and submitted entirely in cassette "G1." The remaining soft tissue fragments are submitted in a biopsy bag in cassette "G2." (Dictated by [REDACTED])

Specimen H is received in formalin and is labeled with the patient's name, medical record number and "more LVL 7 lymph node." It consists of a single lymph node with attached fibrofatty tissue. The lymph node measures 1.3 x 0.8 x 0.4 cm. The lymph node is bisected and submitted entirely in cassette "H1." (Dictated by [REDACTED])

CASSETTE SUMMARY:

E1FS: Bronchial margin

Printed by:
Printed on:

[page 5 of 5]
[REDACTED]

[REDACTED]

E2: Vascular margin
E3: Hilar lymph nodes
E4: Tumor in relation to bronchus
E5,E6: Tumor in relation to pleura
E7,E8: Representative sections of discontinuous nodules adjacent to pleura
E9: Tumor involving intraparenchymal lymph nodes
E10,E11: Tumor in relation to adjacent lung parenchyma
E12: Representative sections of tumor
E13: Representative section of patchy consolidation in superior lobe
E14: Representative section of middle lobe
E15: Representative section of lower lobe

[REDACTED]

Intraoperative Consult Diagnosis

A1FS: LYMPH NODE #7 (FROZEN SECTION): NEGATIVE FOR CARCINOMA.
B1FS: LYMPH NODE #4R (FROZEN SECTION): NEGATIVE FOR CARCINOMA.
Frozen section results were communicated to the surgical team and were repeated back by [REDACTED]
p.m. and start time not provided.
E1FS: BRONCHIAL MARGIN (FROZEN SECTION): NEGATIVE.
Frozen section results were communicated to the surgical team and were repeated back by [REDACTED]

[REDACTED]

Microscopic Description

Microscopic examination performed.

[REDACTED]

Printed by:
Printed on:

[REDACTED]

Source: NCI Genomic Data Commons file e42af451-cc70-4e87-9e2a-7df3798e0a2a (TCGA-94-8490.EF5AF5E3-88F5-4651-A7FE-F56B0BEA6ED8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).